Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5765, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5765-01A (Primary Tumor).

TCGA-CH-5765

Diagnosis

1. Infiltrates of a predominantly moderately differentiated adenocarcinoma of the prostate on both sides. Maximum tumor diameter 3.5 cm. Extensive perineural tumor infiltration. Extraprostatic tumor growth in the right rectolateral region. No identifiable invasion of the vessels. Tumor-free seminal vesicles.
2. Four tumor-free lymph nodes (0/4).
3. Two tumor-free lymph nodes (0/3).

amended after consultation with

Remark

3+4=7

Tumor classification: pT3a, L0, V0, pN0 (0/7); Gleason 4+3=7 (approx. 40% Gleason 4).

At several points the tumor extends to within less than 0.5 mm of the preparation margin, but there is not evidence of indirect contact with the color labeling.

Source: NCI Genomic Data Commons file 3dff7846-88cb-4f1b-b417-5f97ecf64237 (TCGA-CH-5765.BF80F60E-D5C8-4A5B-B523-358C51AD7D2C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).